Surgical pathology report (de-identified scan), TCGA case TCGA-NP-A5H6, project TCGA-KICH (Kidney Chromophobe), tissue source site International Genomics Consortium, specimen TCGA-NP-A5H6-01A (Primary Tumor).

ICD-6-3

Carcinoma, renal cell
Chromophobe type 8317/3
Site @ Kidney NOS C64.9

JW 12/24/12

Sex: Male
D.O.B.:
MRN #:

SPECIMEN INFORMATION

Accession #:

Acct / Reg

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left kidney, radical nephrectomy:

Tumor Characteristics:

1. Histologic type: Renal cell carcinoma, chromophobe type.
2. Tumor site: Left kidney, upper pole.
3. Tumor focality: Unifocal.
4. Tumor size: 8.0 x 6.5 x 6.0 cm.
5. Macroscopic/microscopic extent of tumor: Tumor is confined to the kidney; with no evidence of transcapsular or perinephric soft tissue invasion.
6. Nuclear grade: Fuhrman grade 3-4/4.
7. Lymphovascular space invasion: No.
8. Sarcomatoid features: No.

Surgical Margin Status:

1. Vascular, ureteral, and perinephric margins are all negative for tumor.

Lymph Node Status:

1. No lymph nodes are identified with the specimen.

Other:

1. TNM stage: T2a NX MX.

Electronic Signature:

COMMENTS:

Representative sections of this tumor have also been reviewed

concur with the diagnosis.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Abdominal mass, unspecified site

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received labeled left kidney. The specimen consists of a kidney with attached perinephric fat that measures 28.0 x 16.0 x 7.5 cm, and weighs 1101 gm. There is no adrenal gland attached to the specimen. The ureter measures 10.0 cm in length and up to 0.5 cm diameter. The surface is gray-tan to brown-tan. On opening the ureter, the mucosal surface is light tan and reveals normal mucosal folds. There is no material or lesions identified. The renal artery measures 2.5 cm in length and 0.5 cm in diameter and is grossly unremarkable. The renal vein measures 2.0 cm in length and up to 1.0 cm in diameter, and is likewise grossly unremarkable. At the hilum, there are no lymph nodes identified. The soft tissue resected margin is yellow to brown-tan with slight adhesions. The margin is inked. The kidney is bisected and reveals a circumscribed brown-tan to yellow-tan hemorrhagic mass within the upper pole measuring 8.0 x 6.5 x 6.0 cm. On sectioning, the mass appears grossly confined to the capsule. There is no invasion into the surrounding perinephric fat. The mass comes within 0.1 cm of the inked resected margin. The mass does not involve the renal calices or pelvis. The lining of the renal calices and pelvis is gray-tan, unremarkable. The surrounding renal cortex measures up to 1.0 cm, is brown-tan, and shows a well-demarcated corticomedullary junction. There are no other lesions identified grossly. Received with the specimen are three cassettes, one green, one yellow and one blue, labeled with the yellow additionally labeled -16, the green additionally labeled -17, and the blue additionally labeled -18. Representative sections are submitted in cassettes labeled renal artery and vein -- 6; surrounding uninvolved kidney -- 7.

Criteria	more to chromophobe	12/24/12	Yes	No

Source: NCI Genomic Data Commons file df4f73dc-9afb-4592-8135-20ac14f40c99 (TCGA-NP-A5H6.F5F15B2B-759D-4195-8C33-33C1D6DF8F25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).